Somatic mutation profile of tumor specimen ALCH-B38C-TTP1-A (aliquot ALCH-B38C-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B38C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,081 days).
Specimen ALCH-B38C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 773458c3-e625-4a0a-bf62-123b217c62ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B38C-NB1-A (Blood Derived Normal), aliquot ALCH-B38C-NB1-A-1-1-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0030cf3-a328-415a-9cfb-29731188479d

The open-access MAF lists 222 somatic variants for this specimen: 151 protein-altering or splice-affecting, 42 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 42, Intron 15, RNA 9, Nonsense Mutation 8, Frame Shift Del 5, Splice Site 3, 5'UTR 2, 3'UTR 2, Splice Region 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 78/364 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 77/213 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as COSV51938138, COSV51942762; called by muse, mutect2, varscan2
- ASXL3 | c.6550C>A p.P2184T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.007); catalogued as COSV99324659; called by muse, mutect2, varscan2
- BTBD7 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58284778; called by muse, mutect2, varscan2
- CES3 | c.893_895del p.G298del | In Frame Del (DEL) | VAF 7/85 reads (8%) | catalogued as rs1567556435; called by mutect2, pindel
- CHD8 | c.521A>T p.H174L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.017); catalogued as COSV104433662; called by muse, mutect2, varscan2
- CHL1 | c.2165C>A p.A722D (on ENST00000397491 / NM_001253387.1; = p.A738D on NM_006614.4) | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99851861; called by muse, mutect2, varscan2
- CSMD1 | c.8599G>A p.A2867T (on ENST00000520002; = p.A2866T on NM_033225.6) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV59403550; called by muse, mutect2, varscan2
- CSMD1 | c.6148C>A p.L2050I (on ENST00000520002; = p.L2049I on NM_033225.6) | Missense Mutation (SNP) | VAF 97/421 reads (23%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.994); catalogued as COSV59396364; called by muse, mutect2, varscan2
- CSMD1 | c.1687G>T p.E563* (on ENST00000520002; = p.E562* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | catalogued as COSV59405889; called by muse, mutect2, varscan2
- DCAF4L2 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV100150373, COSV60477494; called by muse, mutect2, varscan2
- DGKB | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 35/160 reads (22%) | catalogued as COSV51805011; called by muse, mutect2, varscan2
- DPP10 | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59695255; called by muse, mutect2, varscan2
- GABRB1 | c.1024A>G p.S342G | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1256833128; called by muse, mutect2, varscan2
- GPR158 | c.1489G>A p.G497R | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285726905, COSV66275590; called by muse, mutect2
- HCN1 | c.1771C>A p.L591I | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV57522694; called by muse, mutect2, varscan2
- HDAC4 | c.2890G>C p.A964P | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013214981; called by muse, mutect2
- ITGAE | c.1894C>A p.R632= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as rs151305570; called by muse, mutect2, varscan2
- KCNH2 | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51141510; called by muse, mutect2, varscan2
- KLK10 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59398648; called by muse, mutect2, varscan2
- LIPC | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as rs747769773; called by muse, mutect2, varscan2
- MROH2B | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV68182068; called by muse, mutect2, varscan2
- MROH5 | c.1688T>C p.M563T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1214490731; called by muse, mutect2
- MUC17 | c.11021C>T p.S3674L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); catalogued as COSV60300453; called by muse, mutect2, varscan2
- MUC5B | c.14116del p.T4706Pfs*4 | Frame Shift Del (DEL) | VAF 32/181 reads (18%) | catalogued as COSV71592533; called by mutect2, pindel, varscan2
- NOTCH2 | c.5434G>T p.A1812S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); catalogued as rs1421138915; called by muse, mutect2
- OAS3 | c.2455C>T p.L819F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs899157715; called by muse, mutect2
- OR2T12 | c.866G>C p.S289T | Missense Mutation (SNP) | VAF 23/279 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV58777466; called by muse, mutect2
- OR56A5 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs767061143; called by muse, mutect2, varscan2
- OR5AP2 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV57258017; called by muse, mutect2, varscan2
- OR5T1 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs780788505, COSV57303760; called by muse, mutect2, varscan2
- OR5T2 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57588702; called by muse, mutect2, varscan2
- PAH | c.1066-1G>T p.X356_splice | Splice Site (SNP) | VAF 22/191 reads (12%) | catalogued as CS1511460, CS1511461, CS982305; called by muse, mutect2, varscan2
- PCDH10 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV52095480; called by muse, mutect2, varscan2
- PCDH11X | c.2130G>T p.E710D | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.282); catalogued as rs1303213887; called by muse, mutect2, varscan2
- PIGT | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as COSV54128860; called by muse, mutect2, varscan2
- POT1 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV62933671; called by muse, mutect2, varscan2
- QKI | c.806A>T p.H269L | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.115); catalogued as rs775809461; called by muse, mutect2, varscan2
- RNF112 | c.502C>G p.P168A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs80118640; called by muse, mutect2, varscan2
- RP1L1 | c.5586G>T p.E1862D | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.258); catalogued as COSV66760279; called by mutect2, varscan2
- RYR2 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63682810; called by muse, mutect2, varscan2
- RYR2 | c.1543G>T p.A515S | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.306); catalogued as COSV63670696; called by muse, mutect2, varscan2
- SALL1 | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV99179210; called by muse, mutect2, varscan2
- SIGLEC1 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.116); catalogued as rs149852645; called by muse, mutect2, varscan2
- SIX6 | c.625G>C p.G209R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV59802078; called by muse, mutect2, varscan2
- SLC8A1 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100247151; called by muse, mutect2, varscan2
- STON2 | c.2183G>T p.R728L (on ENST00000649389 / NM_001366849.2; = p.R671L on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs760033415, COSV99964247, COSV99964663; called by muse, mutect2, varscan2
- TFDP2 | c.796C>A p.P266T (on ENST00000489671 / NM_001178139.2; = p.P206T on NM_006286.5) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100051204; called by muse, mutect2, varscan2
- TLR10 | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.311); catalogued as rs768780323; called by muse, mutect2, varscan2
- TMEM40 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV53145840; called by muse, mutect2, varscan2
- TOX3 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763207906; called by muse, mutect2, varscan2
- TRIM72 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as rs769578887, COSV57250671; called by muse, mutect2, varscan2
- ABCB5 | c.3369T>A p.D1123E (on ENST00000404938 / NM_001163941.2; = p.D678E on NM_178559.6) | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACAD11 | c.1784A>G p.H595R | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ADAR | c.3614A>G p.D1205G | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRG4 | c.1479G>T p.L493F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AKAP10 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 88/328 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- APBA2 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- AQP10 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BACH2 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMS1 | c.3757G>T p.D1253Y | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CHRNA1 | c.427G>A p.G143S (on ENST00000261007 / NM_001039523.3; = p.G118S on NM_000079.4) | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4D | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CNNM1 | c.720C>G p.S240R | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.853); called by muse, mutect2
- CNR2 | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- CSF2RB | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- CYP27A1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DAO | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DENND2A | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.067); called by mutect2, varscan2
- EFTUD2 | c.2818A>G p.R940G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAAH | c.389G>T p.R130M | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2
- FAM214A | c.2442G>T p.L814F | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FAR2 | c.1485C>G p.F495L | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FBLN7 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCER1A | c.474C>A p.N158K | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- GPR139 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- HEG1 | c.761C>G p.T254S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGHV7-81 | c.46+1G>T p.X16_splice | Splice Site (SNP) | VAF 45/261 reads (17%) | called by muse, mutect2
- IL21R | c.1113C>A p.Y371* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- IMPACT | c.845A>T p.N282I | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INTS5 | c.2773G>T p.G925C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- KRT16 | c.541del p.A181Pfs*50 | Frame Shift Del (DEL) | VAF 92/277 reads (33%) | called by mutect2, pindel, varscan2
- KRT17 | c.396C>G p.S132R | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LONP2 | c.1052A>G p.K351R | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC70 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- LTBP4 | c.261C>G p.C87W (on ENST00000308370 / NM_001042544.1; = p.C50W on NM_003573.2) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- LYNX1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAT2B | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MN1 | c.3388C>A p.P1130T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- MSC | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC5B | c.9995T>A p.V3332E | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MXRA5 | c.6649G>T p.G2217* | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | called by muse, mutect2, varscan2
- NEB | c.16274G>T p.R5425I | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- NEU4 | c.1290G>T p.E430D (on ENST00000391969 / NM_001167602.3; = p.E442D on NM_080741.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by mutect2, varscan2
- NFATC2 | c.2727T>A p.N909K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKX2-5 | c.625C>G p.P209A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.473); called by muse, varscan2
- NOTCH2 | c.5433G>T p.Q1811H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- NOTCH4 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NPAP1 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- NRXN2 | c.4460A>T p.E1487V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ODF3L1 | c.50del p.P17Qfs*39 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- OLFML2B | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4B1 | c.727A>T p.T243S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PDE6C | c.15C>G p.N5K | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP5K1B | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLRG1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 39/467 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- PPP1R16B | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- PREX2 | c.606A>T p.Q202H | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PXDNL | c.1577A>T p.K526M | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PYGM | c.1000-4C>T | Splice Region (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- PYROXD2 | c.285G>T p.R95S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, varscan2
- RHCG | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHOT2 | c.1654G>T p.V552L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS2 | c.3928G>T p.G1310C | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SCN3A | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 76/491 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SGIP1 | c.1364G>C p.S455T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SGMS1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA7 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SIDT1 | c.1577T>A p.L526Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLC13A5 | c.718T>A p.L240M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC17A6 | c.458+1G>C p.X153_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- SLC25A31 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC7A1 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMCO2 | c.968G>T p.W323L | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPAG17 | c.2677A>T p.K893* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2341C>A p.H781N | Missense Mutation (SNP) | VAF 109/402 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SPECC1L | c.2248del p.Q750Rfs*8 | Frame Shift Del (DEL) | VAF 41/275 reads (15%) | called by mutect2, pindel, varscan2
- SVEP1 | c.588T>A p.D196E | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- SWT1 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- SYTL5 | c.1713G>T p.K571N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- TANC2 | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TESC | c.371C>G p.S124W | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TG | c.3364dup p.A1122Gfs*61 | Frame Shift Ins (INS) | VAF 33/189 reads (17%) | called by mutect2, pindel, varscan2
- THSD1 | c.1936A>G p.R646G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- TMEM239 | c.170C>A p.A57D (on ENST00000361033 / NM_001318207.1; = p.A14D on NM_001167670.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TNFRSF17 | c.12G>T p.M4I | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TRIP4 | c.827G>C p.S276T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- TRPS1 | c.929T>A p.V310E (on ENST00000220888 / NM_001330599.2; = p.V323E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBE2Q2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- ZCWPW2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX4 | c.10070C>A p.P3357Q | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ZFP42 | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFP64 | c.39G>C p.W13C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- ZIM3 | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZKSCAN5 | c.369del p.V124* | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel
- ZNF234 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF281 | c.1214A>T p.K405I | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ZNF324B | c.1331A>T p.Q444L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF736 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 78/456 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AHNAK | c.3906G>A p.P1302= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as rs775437833, COSV99947598; called by muse, mutect2, varscan2
- AKAP6 | c.5634T>C p.N1878= | Silent (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- ANO3 | c.2460T>A p.G820= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2
- C22orf42 | c.600A>C p.S200= | Silent (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- CCKBR | c.148C>A p.R50= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100582928; called by muse, mutect2, varscan2
- CFC1 | c.210G>T p.P70= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as rs201242330; called by muse, mutect2
- DCX | c.219C>A p.S73= | Silent (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- DEFB128 | c.249C>A p.I83= | Silent (SNP) | VAF 70/389 reads (18%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1239G>A p.Q413= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV70098594; called by muse, mutect2
- DTNA | c.1947T>A p.S649= | Silent (SNP) | VAF 54/186 reads (29%) | called by muse, mutect2, varscan2
- GCH1 | c.282G>T p.T94= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- GDF11 | c.768C>A p.G256= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs1182075371, COSV57690054; called by muse, mutect2, varscan2
- GFY | c.618C>A p.T206= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- HMCN1 | c.15495C>T p.D5165= | Silent (SNP) | VAF 43/261 reads (16%) | called by muse, mutect2, varscan2
- HYDIN | c.6963G>T p.G2321= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV99992864; called by muse, mutect2, varscan2
- IL4R | c.52C>T p.L18= | Silent (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- KDM4E | c.738C>A p.I246= | Silent (SNP) | VAF 43/279 reads (15%) | catalogued as rs1555102816; called by muse, mutect2, varscan2
- KRTAP21-1 | c.45C>A p.G15= | Silent (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- LAMA1 | c.225C>T p.N75= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs555597971; called by muse, mutect2, varscan2
- MAP4K4 | c.2256G>T p.V752= (on ENST00000347699 / NM_001242559.2; = p.V670= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- NALCN | c.1260G>T p.L420= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1247503218; called by muse, mutect2
- NR3C2 | c.963G>C p.T321= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100679896; called by muse, mutect2, varscan2
- NRG3 | c.1797C>A p.P599= (on ENST00000404547 / NM_001370084.1; = p.P575= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 66/313 reads (21%) | catalogued as COSV64575619; called by muse, mutect2, varscan2
- OGDHL | c.2346C>G p.P782= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV65101406, COSV65104449; called by muse, mutect2, varscan2
- OR2T2 | c.636A>C p.L212= | Silent (SNP) | VAF 122/388 reads (31%) | called by mutect2, varscan2
- OR52B2 | c.768A>T p.P256= | Silent (SNP) | VAF 60/341 reads (18%) | called by muse, mutect2, varscan2
- PABPC5 | c.525G>T p.V175= | Silent (SNP) | VAF 50/105 reads (48%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.540G>T p.L180= | Silent (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- PER2 | c.1326C>T p.D442= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs970198349; called by muse, mutect2
- PRDM8 | c.997C>A p.R333= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- PRR35 | c.1266G>T p.L422= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- RBMXL2 | c.963C>G p.G321= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- SFMBT2 | c.2583G>A p.P861= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs569709510, COSV62808515; called by muse, mutect2, varscan2
- SORT1 | c.1857A>T p.I619= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- SOX6 | c.648A>T p.A216= | Silent (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- SPTA1 | c.2058C>T p.A686= | Silent (SNP) | VAF 87/396 reads (22%) | called by muse, mutect2, varscan2
- TENM4 | c.3780C>G p.V1260= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- TNR | c.255C>A p.A85= | Silent (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- TRAV17 | c.333G>A p.T111= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs749276411; called by muse, mutect2
- VAX2 | c.204C>A p.P68= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- VCAN | c.6921G>T p.V2307= | Silent (SNP) | VAF 99/433 reads (23%) | called by muse, mutect2, varscan2
- ZIM2 | c.966C>A p.S322= | Silent (SNP) | VAF 67/235 reads (29%) | called by muse, mutect2, varscan2
- ASNS | c.1138-65G>T | Intron (SNP) | VAF 35/185 reads (19%) | called by muse, mutect2, varscan2
- C4orf36 | c.65+1389G>A | Intron (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- CACNA1C | c.1481+583G>T | Intron (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- CHIT1 | c.915+49C>A | Intron (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- CST9LP1 | n.117C>A | RNA (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- EGFR | c.2469+29G>T | Intron (SNP) | VAF 26/87 reads (30%) | catalogued as COSV99291046; called by muse, mutect2, varscan2
- GABRG3 | c.1123-1930G>A | Intron (SNP) | VAF 44/210 reads (21%) | catalogued as rs1221046611; called by muse, mutect2, varscan2
- GCLC | c.1402-22C>T | Intron (SNP) | VAF 33/256 reads (13%) | catalogued as rs1361112447; called by muse, mutect2, varscan2
- GNG7 | c.-78+3349G>C | Intron (SNP) | VAF 32/172 reads (19%) | catalogued as rs1434004951; called by muse, mutect2, varscan2
- IQUB | c.1759-1203G>T | Intron (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- ITGB2 | c.1156-31G>A | Intron (SNP) | VAF 23/103 reads (22%) | catalogued as rs546901205; called by muse, mutect2, varscan2
- LAMA2 | c.8076-12A>G | Intron (SNP) | VAF 41/160 reads (26%) | called by muse, mutect2, varscan2
- LINC01299 | n.2144G>A | RNA (SNP) | VAF 51/337 reads (15%) | called by muse, mutect2, varscan2
- LRRC55 | c.*2A>T | 3'UTR (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- MED13L | c.*25G>T | 3'UTR (SNP) | VAF 28/224 reads (13%) | called by muse, varscan2
- NOC2LP2 | n.1864G>T | RNA (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1863G>T | RNA (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- NPEPL1 | chr20:58691823 G>T | 5'Flank (SNP) | VAF 67/265 reads (25%) | called by muse, mutect2, varscan2
- NRXN1 | c.833-32760G>T | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- OR2L1P | n.609C>A | RNA (SNP) | VAF 62/198 reads (31%) | called by muse, mutect2, varscan2
- OR5E1P | n.576C>A | RNA (SNP) | VAF 26/96 reads (27%) | catalogued as rs1564838926; called by muse, mutect2, varscan2
- PRKAG2 | c.684+11_684+13dup | Intron (INS) | VAF 9/88 reads (10%) | called by mutect2, pindel, varscan2
- RIMS2 | c.2084-940G>A | Intron (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- SFTPB | c.-17C>A | 5'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.646C>A | RNA (SNP) | VAF 86/418 reads (21%) | called by muse, mutect2, varscan2
- SSPOP | n.10916G>T | RNA (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- SSPOP | n.13647C>A | RNA (SNP) | VAF 14/67 reads (21%) | catalogued as COSV65129305; called by muse, mutect2, varscan2
- USP46 | c.117+1398G>T | Intron (SNP) | VAF 43/217 reads (20%) | called by muse, mutect2, varscan2
- WAC | c.-10C>A | 5'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
